Somatic mutation profile of tumor specimen TCGA-B0-5106-01A (aliquot TCGA-B0-5106-01A-01D-1421-08) from TCGA case TCGA-B0-5106, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 64.5 years (23,547 days).
Specimen TCGA-B0-5106-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22667d74-a054-428e-840b-c7aea58d9e2a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5106-11A (Solid Tissue Normal), aliquot TCGA-B0-5106-11A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ed72bec-7ff5-4e82-a601-07510b2e84bd

The open-access MAF lists 85 somatic variants for this specimen: 64 protein-altering or splice-affecting, 19 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 19, Frame Shift Del 6, Nonsense Mutation 5, In Frame Del 1, Splice Site 1, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.336C>A p.Y112* | Nonsense Mutation (SNP) | VAF 18/34 reads (53%) | hotspot (GDC flag); catalogued as CM951282, COSV56555541, COSV56559171; called by muse, varscan2
- ALPI | c.464C>A p.A155D | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55015304; called by muse, mutect2, varscan2
- AMDHD2 | c.1147G>A p.V383M (on ENST00000293971 / NM_001330449.2; = p.V413M on NM_015944.4) | Missense Mutation (SNP) | VAF 52/245 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1306197212, COSV53549555; called by muse, mutect2, varscan2
- ANKRD39 | c.488A>G p.K163R | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.017); catalogued as COSV58412941; called by muse, mutect2, varscan2
- CACNA1A | c.5821C>T p.Q1941* | Nonsense Mutation (SNP) | VAF 5/57 reads (9%) | catalogued as COSV64204141; called by muse, mutect2
- CCDC180 | c.4256A>C p.N1419T | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.422); catalogued as COSV63832283; called by muse, mutect2, varscan2
- CCDC61 | c.1100A>C p.Q367P | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as rs1026391943, COSV50517117; called by muse, mutect2, varscan2
- CDC14A | c.733T>C p.Y245H | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.013); catalogued as rs1295136193, COSV60560356; called by muse, mutect2, varscan2
- CHAF1A | c.526C>G p.L176V | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.382); catalogued as COSV56674394; called by muse, mutect2, varscan2
- CUL9 | c.3776G>T p.S1259I | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52731205; called by muse, mutect2, varscan2
- DHX15 | c.1655A>T p.D552V | Missense Mutation (SNP) | VAF 85/357 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV61028204; called by muse, mutect2, varscan2
- EVX1 | c.31C>G p.L11V | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs1428622382, COSV56085683; called by muse, mutect2, varscan2
- FHOD3 | c.533A>G p.Y178C | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57179867; called by muse, mutect2, varscan2
- FHOD3 | c.913A>T p.K305* | Nonsense Mutation (SNP) | VAF 46/152 reads (30%) | catalogued as COSV57179878; called by muse, mutect2, varscan2
- GIMAP8 | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.117); catalogued as rs761170315, COSV56229886; called by muse, mutect2, varscan2
- GON4L | c.4957C>A p.L1653I | Missense Mutation (SNP) | VAF 51/214 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV55197792; called by muse, mutect2, varscan2
- HECTD2 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 96/317 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.087); catalogued as COSV53222736; called by muse, mutect2, varscan2
- HRC | c.1106T>A p.V369D | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.143); catalogued as COSV53257486; called by muse, mutect2, varscan2
- IRX1 | c.370C>A p.Q124K | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV57360798; called by muse, mutect2, varscan2
- KDM5C | c.1536C>G p.C512W | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64766753; called by muse, mutect2, varscan2
- KIAA1210 | c.2314A>G p.R772G | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1299846067, COSV68178418, COSV99081431; called by muse, mutect2, varscan2
- LAMTOR5 | c.53T>C p.I18T (on ENST00000602318 / NM_001382293.1; = p.I100T on NM_006402.3) | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV56679225; called by muse, mutect2, varscan2
- LINGO1 | c.576C>G p.S192R | Missense Mutation (SNP) | VAF 57/178 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.619); catalogued as COSV62437691; called by muse, mutect2, varscan2
- MRPL22 | c.101A>T p.H34L | Missense Mutation (SNP) | VAF 45/222 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV54558935; called by muse, mutect2, varscan2
- NAT9 | c.127T>C p.S43P | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52854039; called by muse, mutect2, varscan2
- NFAT5 | c.3358C>A p.Q1120K | Missense Mutation (SNP) | VAF 178/447 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as COSV100590375, COSV63029729; called by muse, mutect2, varscan2
- NIPSNAP3B | c.185T>C p.L62P | Missense Mutation (SNP) | VAF 81/328 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66106748; called by muse, mutect2, varscan2
- NPFFR2 | c.1530G>A p.M510I | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as rs753806594, COSV58151741; called by muse, mutect2, varscan2
- NUP210 | c.664A>T p.I222F | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as COSV54409385; called by muse, mutect2, varscan2
- OR1D2 | c.306C>A p.Y102* | Nonsense Mutation (SNP) | VAF 57/215 reads (27%) | catalogued as rs140264769; called by muse, mutect2, varscan2
- PALLD | c.1963C>A p.L655I | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV54986552; called by muse, mutect2, varscan2
- PAN3 | c.1838C>A p.P613Q | Missense Mutation (SNP) | VAF 70/267 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV56705115; called by muse, mutect2, varscan2
- PCDHA5 | c.2315G>T p.S772I | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs782668239, COSV65354337; called by muse, mutect2, varscan2
- PITPNM2 | c.1423C>A p.L475M | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.11); catalogued as COSV54903925; called by muse, mutect2, varscan2
- PLCD4 | c.1664T>C p.L555P | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV68743905; called by muse, mutect2, varscan2
- PLPPR4 | c.1143A>T p.R381S | Missense Mutation (SNP) | VAF 45/153 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV64566850; called by muse, mutect2, varscan2
- POTEE | c.1200A>C p.K400N | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.006); catalogued as COSV58236555; called by muse, mutect2, varscan2
- PSMC6 | c.838G>A p.G280R (on ENST00000612399; = p.G266R on NM_002806.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV71629065; called by muse, mutect2
- PTPN11 | c.349C>T p.L117F | Missense Mutation (SNP) | VAF 55/203 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV61010845; called by muse, mutect2, varscan2
- SELENOI | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53145657; called by muse, mutect2, varscan2
- SLC17A1 | c.985A>T p.N329Y | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV55080309; called by muse, mutect2, varscan2
- SLC3A2 | c.965A>G p.Q322R | Missense Mutation (SNP) | VAF 58/197 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.043); catalogued as COSV58604156; called by muse, mutect2, varscan2
- SLC44A4 | c.1393C>A p.L465I | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV57668150; called by muse, mutect2, varscan2
- SPTBN1 | c.6615T>A p.N2205K | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV61690652; called by muse, mutect2, varscan2
- STX7 | c.613A>T p.S205C | Missense Mutation (SNP) | VAF 52/248 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100908535, COSV63398954; called by muse, varscan2
- STX7 | c.612T>A p.D204E | Missense Mutation (SNP) | VAF 50/244 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.923); catalogued as COSV63398963; called by muse, varscan2
- TACR3 | c.1243C>G p.P415A | Missense Mutation (SNP) | VAF 113/605 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV59204447; called by muse, mutect2, varscan2
- TIAF1 | c.194C>A p.P65H | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.865); catalogued as COSV62869984; called by muse, mutect2, varscan2
- TRIOBP | c.4106G>C p.S1369T | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.02); catalogued as COSV60380802; called by muse, mutect2, varscan2
- TUT7 | c.819G>T p.K273N | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.852); catalogued as COSV52897058; called by muse, mutect2, varscan2
- UCHL3 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 62/257 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.258); catalogued as COSV66460019; called by muse, mutect2, varscan2
- UGT1A8 | c.522C>A p.C174* | Nonsense Mutation (SNP) | VAF 106/414 reads (26%) | catalogued as COSV65081971; called by muse, mutect2, varscan2
- UTRN | c.4273C>G p.R1425G | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV62340896; called by muse, mutect2, varscan2
- XIRP1 | c.4949C>T p.S1650L | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV61137742, COSV61139642; called by muse, mutect2, varscan2
- XIRP1 | c.4948T>A p.S1650T | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV61139656; called by muse, mutect2, varscan2
- ZNF91 | c.2594_2597del p.Q865Lfs*9 | Frame Shift Del (DEL) | VAF 36/150 reads (24%) | catalogued as rs750131005; called by pindel, varscan2
- ZSWIM5 | c.1652C>A p.S551Y | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62735457; called by muse, mutect2, varscan2
- DDX50 | c.1949_1958del p.D650Gfs*95 | Frame Shift Del (DEL) | VAF 33/131 reads (25%) | called by pindel, varscan2
- FLT4 | c.3443_3448del p.M1148_L1149del | In Frame Del (DEL) | VAF 41/131 reads (31%) | called by mutect2, pindel, varscan2
- NT5C2 | c.43_44del p.M15Afs*3 | Frame Shift Del (DEL) | VAF 110/501 reads (22%) | called by pindel, varscan2
- SECISBP2 | c.575-7_575-1delinsTT p.X192_splice | Splice Site (DEL) | VAF 18/86 reads (21%) | called by pindel, varscan2*
- SUDS3 | c.659del p.L220Rfs*4 | Frame Shift Del (DEL) | VAF 68/306 reads (22%) | called by mutect2, pindel, varscan2
- TSPYL1 | c.1190_1191del p.K397Rfs*15 | Frame Shift Del (DEL) | VAF 25/109 reads (23%) | called by mutect2, pindel, varscan2
- VCL | c.417_423del p.K139Nfs*28 | Frame Shift Del (DEL) | VAF 23/148 reads (16%) | called by mutect2, pindel, varscan2
- AKAP12 | c.933C>A p.T311= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV53578224; called by muse, mutect2, varscan2
- CFAP61 | c.912G>A p.L304= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV55637409, COSV99070483; called by muse, mutect2, varscan2
- DNAJA4 | c.327A>G p.V109= (on ENST00000343789; = p.V138= on NM_018602.3) | Silent (SNP) | VAF 67/366 reads (18%) | catalogued as COSV59426278; called by muse, mutect2, varscan2
- GLIS1 | c.1860C>A p.T620= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as COSV56552035; called by muse, mutect2, varscan2
- HSPA8 | c.192C>T p.T64= | Silent (SNP) | VAF 27/98 reads (28%) | catalogued as COSV57084729; called by muse, mutect2, varscan2
- HTT | c.2757A>G p.E919= | Silent (SNP) | VAF 39/128 reads (30%) | catalogued as COSV61865318; called by muse, mutect2, varscan2
- JADE2 | c.276T>C p.P92= | Silent (SNP) | VAF 24/92 reads (26%) | catalogued as COSV50921881; called by muse, mutect2, varscan2
- MROH9 | c.1368G>T p.L456= | Silent (SNP) | VAF 75/261 reads (29%) | catalogued as COSV63012330; called by muse, mutect2, varscan2
- MUC5B | c.6114C>A p.T2038= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as rs758229521, COSV71594007; called by muse, mutect2, varscan2
- NDN | c.102G>A p.P34= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs748977155, COSV59360402, COSV59360507; called by muse, mutect2
- OR14K1 | c.837A>G p.A279= | Silent (SNP) | VAF 30/98 reads (31%) | catalogued as COSV99315407; called by muse, mutect2, varscan2
- PCDHGA10 | c.1764C>T p.P588= | Silent (SNP) | VAF 66/307 reads (21%) | catalogued as rs773327918, COSV53984590; called by muse, mutect2, varscan2
- PHACTR1 | c.792G>A p.Q264= | Silent (SNP) | VAF 28/95 reads (29%) | catalogued as COSV60673293; called by muse, mutect2, varscan2
- PKHD1L1 | c.11790T>A p.V3930= | Silent (SNP) | VAF 55/191 reads (29%) | catalogued as COSV65747362; called by muse, mutect2, varscan2
- PLEC | c.2943C>T p.S981= (on ENST00000322810 / NM_201380.4; = p.S871= on NM_000445.5) | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs781911470, COSV59660150; called by muse, varscan2
- TUBG1 | c.807C>T p.L269= | Silent (SNP) | VAF 41/196 reads (21%) | catalogued as rs145699955; called by muse, mutect2, varscan2
- TYK2 | c.2295C>T p.G765= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as rs914487132, COSV53389174; called by muse, mutect2, varscan2
- YAP1 | c.1432T>C p.L478= (on ENST00000282441 / NM_001130145.3; = p.L424= on NM_006106.5) | Silent (SNP) | VAF 76/252 reads (30%) | catalogued as rs1473347801, COSV56776665; called by muse, mutect2, varscan2
- ZBTB44 | c.726T>A p.P242= | Silent (SNP) | VAF 33/108 reads (31%) | catalogued as COSV63537814; called by muse, mutect2, varscan2
- RPL7P3 | chr20:62570542 G>A | 5'Flank (SNP) | VAF 52/115 reads (45%) | called by muse, mutect2, varscan2
- SLC47A1 | c.921+1629C>T | Intron (SNP) | VAF 35/161 reads (22%) | catalogued as rs778131405, COSV54503991, COSV99565282; called by muse, mutect2, varscan2
